Surgical pathology report (de-identified scan), TCGA case TCGA-IN-A7NT, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-IN-A7NT-01A (Primary Tumor).

[page 1 of 2]
Collection Date:

FINAL DIAGNOSIS:

PART 1: SOFT TISSUE, BASE OF LEFT GASTRIC, EXCISION -
THREE BENIGN LYMPH NODES, NEGATIVE FOR TUMOR (0/3).

PART 2: SOFT TISSUE, MID PORTION OF LEFT GASTRIC, EXCISION -
ONE BENIGN LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 3: OMENTUM, RESECTION -
MATURE ADIPOSE TISSUE, NEGATIVE FOR TUMOR.

PART 4: LYMPH NODE, SUBCARINAL, NEAR CARINA, LYMPHADENECTOMY -
ONE BENIGN ANTHRACOTIC LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 5: LYMPH NODE, SUBCARINAL, NEAR LEFT MAIN STEM BRONCHUS, LYMPHADENECTOMY -
ONE BENIGN ANTHRACOTIC LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 6: LYMPH NODE, SUBCARINAL, NEAR AORTA, LYMPHADENECTOMY -
TWO BENIGN ANTHRACOTIC LYMPH NODES, NEGATIVE FOR TUMOR (0/2).

PART 7: LYMPH NODE, SUBCARINAL, NEAR LEFT ATRIUM, LYMPHADENECTOMY -
TWO BENIGN ANTHRACOTIC LYMPH NODES, NEGATIVE FOR TUMOR (0/2).

PART 8: LYMPH NODE, SUBCARINAL, NEAR AZYGOUS, LYMPHADENECTOMY -
ONE BENIGN ANTHRACOTIC LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 9: LYMPH NODE, SUBCARINAL, LYMPHADENECTOMY -
ONE BENIGN ANTHRACOTIC LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 10: LYMPH NODE, LEVEL 7, LYMPHADENECTOMY -
TWO BENIGN ANTHRACOTIC LYMPH NODES, NEGATIVE FOR TUMOR (0/2).

PART 11: LYMPH NODE, PARAESOPHAGEAL, NEAR AZYGOUS, LYMPHADENECTOMY -
ONE BENIGN ANTHRACOTIC LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 12: LYMPH NODE, PARAESOPHAGEAL, NEAR AORTA, LYMPHADENECTOMY -
TWO BENIGN ANTHRACOTIC LYMPH NODES, NEGATIVE FOR TUMOR (0/2).

PART 13: LYMPH NODE, SUBCARINAL, NEAR RIGHT MAIN BRONCHUS, LYMPHADENECTOMY -
ONE BENIGN ANTHRACOTIC LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 14: ESOPHAGUS AND STOMACH, ESOPHAGOGASTRECTOMY -
A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, 5.0 CM, OF THE ESOPHAGOGASTRIC JUNCTION
INVADING THROUGH THE MUSCULARIS PROPRIA INTO THE PERIESOPHAGEAL ADVENTITIAL SOFT TISSUE.
B. ANGIOLYMPHATIC INVASION PRESENT.
C. NO PERINEURAL INVASION IDENTIFIED.
D. ALL SURGICAL MARGINS (PROXIMAL ESOPHAGUS, DISTAL GASTRIC AND CIRCUMFERENTIAL ADVENTITIA)
ARE FREE OF TUMOR.
E. FOURTEEN LYMPH NODE, NEGATIVE FOR TUMOR (0/14).
F. PATHOLOGIC STAGE: pT3 N1.
G. BACKGROUND ESOPHAGUS WITH BARRETT'S MUCOSA WITH LOW-GRADE DYSPLASIA.
H. PROXIMAL GASTRIC MUCOSA WITH NO SPECIFIC ABNORMALITY.

ICD O-3

Adenocarcinoma NOS
8/40/13

PART 15: LYMPH NODE, FAT PAD, LYMPHADENECTOMY -
ONE BENIGN LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 16: LYMPH NODE, DISTAL PARAESOPHAGEAL, LYMPHADENECTOMY -
ONE BENIGN ANTHRACOTIC LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

Site Hx junction
C16.0

PART 17: LYMPH NODE, GASTRIC FAT, LYMPHADENECTOMY -
ONE OF ONE LYMPH NODE POSITIVE FOR METASTATIC ADENOCARCINOMA (1/1).

9/24/13

PART 18: "EEA RINGS" EXCISION -

- A. BENIGN ESOPHAGEAL ISSUE COVERED BY UNREMARKABLE SQUAMOUS MUCOSA.
- B. BENIGN GASTRIC TISSUE COVERED BY OXYNTIC MUCOSA WITH MILD INACTIVE CHRONIC INFLAMMATION.
- C. NO EVIDENCE OF INTESTINAL METAPLASIA OR NEOPLASIA.

PART 19: STOMACH, FINAL MARGIN -

- A. BENIGN GASTRIC TISSUE COVERED BY OXYNTIC MUCOSA WITH CHRONIC INFLAMMATION.
- B. NO HELICOBACTER PYLORI ORGANISMS ARE IDENTIFIED ON H&E OR IMMUNOSTAIN.

[page 2 of 2]
CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY ESOPHAGEAL TUMORS****----- MACROSCOPIC -----**

SPECIMEN TYPE: Esophagogastrectomy
TUMOR SITE: Esophagogastric junction (EGJ) region (tumor involves EGJ and epicenter within 5cm of EGJ)
TUMOR SIZE: Greatest dimension: 5.0 cm
Additional dimensions: 3.0 X 0.9 cm

----- MICROSCOPIC -----

HISTOLOGIC TYPE: Adenocarcinoma
HISTOLOGIC GRADE: G3
PATHOLOGIC STAGING (pTNM) pT3
pN1
Number of lymph nodes examined: 35
Number of lymph nodes involved: 1
17 or more regional lymph nodes were identified
pM Not applicable
PRIOR TREATMENT: No prior treatment

MARGINS

Proximal margin uninvolved by invasive carcinoma
Distal margin uninvolved by invasive carcinoma
Distal margin uninvolved by dysplasia
Distal margin uninvolved by intestinal metaplasia
Circumferential (adventitial) margin uninvolved by invasive carcinoma
Present

ANGIOLYMPHATIC INVASION:

ADDITIONAL PATHOLOGIC FINDINGS: Intestinal metaplasia (Barrett's esophagus)
Low grade dysplasia

PIPA Discrepancy		☒

Source: NCI Genomic Data Commons file 5e516a04-f09b-4271-962e-3919310c1cf0 (TCGA-IN-A7NT.61874701-7A2F-4E6F-816C-F53EBE92ECA9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).